Gene-level copy-number profile of tumor specimen TCGA-SB-A76C-01A from TCGA case TCGA-SB-A76C, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; Age at diagnosis: 38.4 years (14,023 days).
Specimen TCGA-SB-A76C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.c4f27255-b0d1-4765-aeed-29ca6c1029b4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-SB-A76C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16c4b4d4-3e01-4ddf-a00e-d96fc48f7864

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,214; copy number 2: 17,111; copy number 3: 28,803; copy number 4: 9,905; copy number 5: 2,334; copy number 6: 153; copy number 7: 298.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-SB-A76C-01A-11D-A434-01): tumor purity 0.64, ploidy 2.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 298 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–4,269,000, 87 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:88,759,700–89,338,528, 1 gene, copy number 7 (within-gene range 4–7): ZNF804B.
- chr7:89,443,946–100,082,548, 210 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,214. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
